Gene-level copy-number profile of tumor specimen TCGA-DC-6156-01A from TCGA case TCGA-DC-6156, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IVA; Age at diagnosis: 62.2 years (22,706 days).
Specimen TCGA-DC-6156-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.b070bf32-e515-4130-a2bf-f0675d5d961c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DC-6156-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f4a346e-e509-4101-9458-d839b0b9e1ad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 520; copy number 2: 10,323; copy number 3: 21,930; copy number 4: 11,117; copy number 5: 10,265; copy number 6: 4,057; copy number 7: 676; copy number 8: 347; copy number 9: 104; copy number 13: 477.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-DC-6156-01): tumor purity 0.44, ploidy 3.58, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:50,082,169–50,906,856, 1 gene (within-gene range 0–2): DLEU1.
- chr13:50,361,410–50,843,939, 3 genes (within-gene range 0–2): RPL34P26, AL158195.1, DLEU7.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,604 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:61,561,569–64,103,131, 34 genes, copy number 7: PTPRG, Y_RNA, RPL10AP6, RNU2-10P, ID2B, PTPRG-AS1, C3orf14, FEZF2, CADPS, AC012519.1, RN7SL863P, RNU6-139P, AC096915.1, LINC00698, KRT8P35, UBL5P3, SYNPR, SYNPR-AS1, RNA5SP134, SNTN, AC104162.1, C3orf49, THOC7, THOC7-AS1, ATXN7, SCAANT1, PSMD6-AS2, AC012557.1, PSMD6, PSMD6-AS1, AC012557.2, PRICKLE2-AS1, U3, LINC00994.
- chr3:64,099,273–64,106,056, 2 genes, copy number 7: PRICKLE2-AS1, PRICKLE2-AS2.
- chr13:18,467,172–48,037,968, 581 genes, copy number 9–13 (within-gene range 2–13) (broad region; genes not listed).
- chr13:59,071,462–114,337,626, 640 genes, copy number 7 (broad region; genes not listed).
- chr20:35,520,852–49,036,693, 347 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 519. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
